Somatic mutation profile of tumor specimen MMRF_2196_1_BM_CD138pos (aliquot MMRF_2196_1_BM_CD138pos_T1_KHS5U_L09510) from MMRF case MMRF_2196, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.6 years (25,043 days).
Specimen MMRF_2196_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d96c8fb4-04c2-44e5-a2d0-05fd77f12059.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2196_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2196_1_PB_Whole_C2_KHS5U_L09509; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0428ec6d-0193-4a94-9935-9a7dcdec821a

The open-access MAF lists 63 somatic variants for this specimen: 21 protein-altering or splice-affecting, 10 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 19, Missense Mutation 18, Silent 10, Intron 6, 5'UTR 4, RNA 2, 5'Flank 1, Splice Region 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFDN | c.4952G>A p.R1651Q (on ENST00000447894 / NM_001366320.1; = p.R1634Q on NM_001207008.1) | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs767873954, COSV60052852; called by muse, mutect2, varscan2
- CCT4 | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1406921017; called by muse, mutect2, varscan2
- FOLR1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs753241819, COSV56616543; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGLV4-60 | c.210G>T p.K70N | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV66503844; called by muse, mutect2, varscan2
- MFSD6L | c.184T>G p.W62G | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61003114; called by muse, mutect2, varscan2
- NKAP | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57631113; called by muse, mutect2, varscan2
- RIMS1 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs1374342255; called by muse, mutect2, varscan2
- RYR2 | c.7453C>T p.L2485F | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.965); catalogued as rs752900705; called by muse, mutect2, varscan2
- ACOT7 | c.1108G>A p.A370T (on ENST00000377855 / NM_181864.3; = p.A360T on NM_007274.4) | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- ACTB | c.363G>A p.Q121= | Splice Region (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- ADGRL2 | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CC2D1A | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 99/226 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CYS1 | c.422A>T p.Y141F | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ELMOD2 | c.629A>T p.N210I | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ESPNL | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 39/52 reads (75%) | SIFT tolerated (0.12); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GNAT1 | c.112G>C p.G38R | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ODF3 | c.688A>T p.K230* | Nonsense Mutation (SNP) | VAF 97/245 reads (40%) | called by muse, mutect2, varscan2
- PHF3 | c.3395T>G p.L1132R | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- STYXL2 | c.551T>G p.I184S | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TAP1 | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- TOX3 | c.797dup p.R267Qfs*8 | Frame Shift Ins (INS) | VAF 54/140 reads (39%) | called by mutect2, pindel, varscan2
- CRYBG1 | c.5415C>A p.I1805= | Silent (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2
- HYDIN | c.7593G>A p.A2531= | Silent (SNP) | VAF 75/193 reads (39%) | catalogued as rs185945967, COSV59253502; called by muse, mutect2, varscan2
- IGHV1-69 | c.219C>T p.I73= | Silent (SNP) | VAF 57/86 reads (66%) | catalogued as rs376252778; called by muse, mutect2, varscan2
- IGHV2-70D | c.339G>C p.T113= | Silent (SNP) | VAF 22/33 reads (67%) | called by muse, varscan2
- IGLV3-19 | c.144C>T p.S48= | Silent (SNP) | VAF 56/65 reads (86%) | catalogued as rs372995146; called by muse, mutect2, varscan2
- KCNV2 | c.390C>G p.T130= | Silent (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- KIF1B | c.5388A>T p.P1796= (on ENST00000377086 / NM_001365952.1; = p.P1750= on NM_015074.3) | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- MAMDC4 | c.1149C>A p.T383= | Silent (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- RGSL1 | c.645C>T p.Y215= | Silent (SNP) | VAF 80/160 reads (50%) | catalogued as rs773748257, COSV54263955; called by muse, mutect2, varscan2
- SMARCA1 | c.1095A>C p.A365= | Silent (SNP) | VAF 61/165 reads (37%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.1399A>T | RNA (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- AP000893.1 | n.707A>G | RNA (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- AQP4 | c.*1738C>T | 3'UTR (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- ATXN2L | c.*10G>A | 3'UTR (SNP) | VAF 33/156 reads (21%) | called by muse, mutect2, varscan2
- BBOX1 | c.-38-46T>G | Intron (SNP) | VAF 21/55 reads (38%) | catalogued as rs1354501938; called by muse, mutect2, varscan2
- CCND1 | c.414+64G>A | Intron (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- CLINT1 | c.*940A>G | 3'UTR (SNP) | VAF 5/88 reads (6%) | catalogued as rs1211024345; called by muse, mutect2
- DTX1 | c.-191G>A | 5'UTR (SNP) | VAF 44/102 reads (43%) | called by muse, varscan2
- DTYMK | chr2:241686886 C>A | 5'Flank (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- EIF2AK3 | c.-144C>G | 5'UTR (SNP) | VAF 55/141 reads (39%) | called by muse, mutect2, varscan2
- FRG2C | c.*366T>C | 3'UTR (SNP) | VAF 22/65 reads (34%) | called by muse, varscan2
- GPC4 | c.-481G>A | 5'UTR (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- GPR88 | c.*68C>T | 3'UTR (SNP) | VAF 37/97 reads (38%) | catalogued as rs1359556329; called by muse, mutect2, varscan2
- GTF2A1 | c.-417C>T | 5'UTR (SNP) | VAF 8/66 reads (12%) | catalogued as rs1429739872, COSV53337129; called by muse, mutect2
- HMGA2 | c.*2105A>G | 3'UTR (SNP) | VAF 23/46 reads (50%) | catalogued as rs1312042572; called by muse, mutect2, varscan2
- KCNC2 | c.*679C>A | 3'UTR (SNP) | VAF 106/264 reads (40%) | called by muse, mutect2, varscan2
- KCNK1 | c.*214G>A | 3'UTR (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2
- MGAT5 | c.*888A>T | 3'UTR (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2, varscan2
- MRPS25 | c.*386A>C | 3'UTR (SNP) | VAF 51/120 reads (43%) | called by muse, mutect2, varscan2
- NKAIN3 | c.472-55166G>A | Intron (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- PCNX2 | c.2864-1939A>T | Intron (SNP) | VAF 44/70 reads (63%) | called by mutect2, varscan2
- PCYT1B | c.*1210C>A | 3'UTR (SNP) | VAF 46/78 reads (59%) | called by muse, mutect2, varscan2
- PLCB2 | c.582+492C>A | Intron (SNP) | VAF 44/88 reads (50%) | called by muse, mutect2, varscan2
- PPP1R16B | c.*37G>A | 3'UTR (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- RSPO4 | c.*1314G>A | 3'UTR (SNP) | VAF 17/42 reads (40%) | catalogued as rs1284770300; called by muse, mutect2, varscan2
- SEC14L1 | c.*2609A>G | 3'UTR (SNP) | VAF 54/128 reads (42%) | called by muse, mutect2, varscan2
- SERPIND1 | c.*430G>A | 3'UTR (SNP) | VAF 54/133 reads (41%) | catalogued as rs1194683009; called by muse, mutect2, varscan2
- SSR1 | c.*397C>T | 3'UTR (SNP) | VAF 42/104 reads (40%) | called by muse, mutect2, varscan2
- TIE1 | c.1043-32G>A | Intron (SNP) | VAF 47/144 reads (33%) | called by muse, mutect2, varscan2
- TPTE | c.*44C>G | 3'UTR (SNP) | VAF 141/830 reads (17%) | catalogued as rs761820843; called by muse, mutect2, varscan2
- TUSC1 | c.*597G>C | 3'UTR (SNP) | VAF 30/100 reads (30%) | catalogued as rs1329941240; called by muse, mutect2, varscan2
- TUSC1 | c.*596G>C | 3'UTR (SNP) | VAF 28/99 reads (28%) | called by muse, mutect2, varscan2
